Somatic mutation profile of cancer-model specimen HCM-BROD-0709-C64-85B (3D Organoid, passage 9; aliquot HCM-BROD-0709-C64-85B-01D-A85K-36), derived from the primary tumor of HCMI case HCM-BROD-0709-C64, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 47.1 years (17,200 days).
Specimen HCM-BROD-0709-C64-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1fa6ff2c-b6b2-4f37-ae0a-1273b7d70d33.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0709-C64-11B (Solid Tissue Normal), aliquot HCM-BROD-0709-C64-11B-01D-A85K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/93c55b12-ac89-467c-86c1-dba315c2790e

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, Frame Shift Ins 1, Nonsense Mutation 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMER1 | c.2689G>A p.D897N | Missense Mutation (SNP) | VAF 131/583 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs749609920, COSV57653782; called by muse, mutect2, varscan2
- BBS4 | c.614T>G p.L205R | Missense Mutation (SNP) | VAF 105/239 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755843033; called by muse, mutect2, varscan2
- IGSF9 | c.3460C>T p.R1154C (on ENST00000368094 / NM_001135050.2; = p.R1138C on NM_020789.4) | Missense Mutation (SNP) | VAF 208/679 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs767665145; called by muse, varscan2
- ARPP21 | c.1411G>A p.A471T | Missense Mutation (SNP) | VAF 14/402 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2
- B3GALNT2 | c.538dup p.Y180Lfs*41 | Frame Shift Ins (INS) | VAF 118/397 reads (30%) | called by mutect2, pindel, varscan2
- DUOX2 | c.2305G>T p.E769* | Nonsense Mutation (SNP) | VAF 155/322 reads (48%) | called by muse, mutect2, varscan2
- ECE1 | c.724A>G p.S242G | Missense Mutation (SNP) | VAF 183/234 reads (78%) | SIFT tolerated (0.68); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OGT | c.651T>C p.A217= | Splice Region (SNP) | VAF 118/310 reads (38%) | called by muse, mutect2, varscan2
- ANKRD62 | c.720A>G p.A240= | Silent (SNP) | VAF 119/323 reads (37%) | catalogued as rs551309335; called by muse, mutect2, varscan2
- RTL8A | c.216C>T p.L72= | Silent (SNP) | VAF 264/658 reads (40%) | catalogued as COSV66188366; called by muse, mutect2, varscan2
- KCTD1 | c.-15-46439C>T | Intron (SNP) | VAF 181/419 reads (43%) | catalogued as rs1389078626; called by muse, mutect2, varscan2
